Somatic mutation profile of tumor specimen 0DZRYI from CCDI case PBCUJB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DZRYI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d55cc74-3b3b-439a-b499-6b617e107e98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZRZ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bfde037-9399-4913-b53d-815afbf29aea

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO18A | c.3904C>T p.R1302C | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1329414528, COSV62869677; called by muse, mutect2, varscan2
- NUP210 | c.4555G>A p.D1519N | Missense Mutation (SNP) | VAF 22/592 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as rs1055400051, COSV54414144; called by muse, mutect2
- XK | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 266/938 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs367651585, COSV101064639; called by muse, mutect2, varscan2
- TBC1D5 | c.168-1G>T p.X56_splice | Splice Site (SNP) | VAF 26/701 reads (4%) | called by muse, mutect2
